Somatic mutation profile of tumor specimen TCGA-DU-A5TY-01A (aliquot TCGA-DU-A5TY-01A-11D-A289-08) from TCGA case TCGA-DU-A5TY, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 46.4 years (16,945 days).
Specimen TCGA-DU-A5TY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44dffb5b-8e37-4930-b4e8-74c9063467b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TY-10A (Blood Derived Normal), aliquot TCGA-DU-A5TY-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ddd123a-a35e-480d-876f-6ab428d3310f

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Intron 2, Frame Shift Del 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR2A | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 156/441 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as COSV54018565; called by muse, mutect2, varscan2
- ASB17 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs148576874; called by muse, mutect2, varscan2
- ASIC3 | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV52520259; called by muse, mutect2, varscan2
- BTBD2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as COSV55307271; called by muse, mutect2, varscan2
- CACNA1E | c.5209G>A p.G1737R | Missense Mutation (SNP) | VAF 82/212 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62381043; called by muse, varscan2
- CDH18 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV56898169; called by muse, mutect2, varscan2
- CPVL | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 16/577 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV99605599; called by muse, mutect2
- CUL9 | c.4154C>G p.S1385C | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52724736; called by muse, mutect2, varscan2
- CYP4V2 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV66504833; called by muse, mutect2, varscan2
- FRK | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200172011, COSV73383788; called by muse, mutect2, varscan2
- FZD9 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.316); catalogued as rs782339488, COSV59988261; called by muse, mutect2, varscan2
- GRM5 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs1287949065; called by muse, mutect2, varscan2
- HMCES | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV67300083; called by muse, mutect2, varscan2
- HOXA5 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 52/1147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178755278, COSV56071906; called by muse, mutect2
- ISLR2 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV62301511; called by muse, mutect2, varscan2
- KRTAP1-5 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV62624013; called by muse, mutect2, varscan2
- KSR2 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56664644; called by muse, mutect2, varscan2
- NAPSA | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV53796604; called by muse, mutect2, varscan2
- OGFRL1 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV64971620; called by muse, mutect2, varscan2
- OPRD1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1392781756, COSV52379939; called by muse, mutect2, varscan2
- PLEKHG4B | c.1510G>A p.V504M (on ENST00000283426; = p.V860M on NM_052909.5) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754520403, COSV52042902; called by muse, mutect2, varscan2
- PTN | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61963008; called by muse, mutect2, varscan2
- RAP2B | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60256680; called by muse, mutect2, varscan2
- RNF128 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as rs146627932, COSV60945012; called by muse, mutect2
- RTL9 | c.4102G>T p.E1368* | Nonsense Mutation (SNP) | VAF 24/209 reads (11%) | catalogued as COSV71825337; called by muse, mutect2, varscan2
- SH2D1A | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as CM056699, COSV63578483; called by muse, mutect2, varscan2
- SHROOM4 | c.762G>T p.M254I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56783530; called by muse, mutect2, varscan2
- SSTR4 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54796704; called by muse, mutect2, varscan2
- SSUH2 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756699925, COSV58028595; called by muse, mutect2, varscan2
- SUV39H1 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV61920194; called by muse, mutect2, varscan2
- TRIM39 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs199883161, COSV64954832; called by muse, mutect2, varscan2
- ZNF385B | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs146268620; called by muse, mutect2, varscan2
- HEPH | c.1384del p.A462Lfs*54 (on ENST00000343002; = p.A195Lfs*54 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- ZNF330 | c.702_703del p.K234Nfs*8 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.1182C>T p.T394= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as COSV63990212; called by muse, mutect2, varscan2
- ANXA9 | c.402C>T p.D134= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs770554982, COSV64484103; called by muse, mutect2, varscan2
- AZIN2 | c.1252C>T p.L418= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs1370642460, COSV53855620; called by muse, mutect2, varscan2
- CCBE1 | c.273C>T p.D91= | Silent (SNP) | VAF 60/257 reads (23%) | catalogued as rs369006324; called by muse, mutect2, varscan2
- DSG1 | c.1860C>T p.N620= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs548157114, COSV57132941; called by muse, mutect2, varscan2
- IGHV1-24 | c.132C>T p.S44= | Silent (SNP) | VAF 105/284 reads (37%) | catalogued as rs200751248; called by muse, mutect2, varscan2
- IQCA1 | c.1866C>T p.F622= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV54494796, COSV54506745; called by muse, mutect2, varscan2
- KCNT1 | c.2331C>T p.Y777= (on ENST00000488444; = p.Y796= on NM_020822.3) | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs530678159, COSV53694910; called by muse, mutect2, varscan2
- KRT24 | c.819C>T p.T273= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs752093858, COSV52879418, COSV52879956; called by muse, mutect2, varscan2
- NNT | c.321A>G p.R107= | Silent (SNP) | VAF 73/162 reads (45%) | catalogued as COSV52922273; called by muse, mutect2, varscan2
- SMC6 | c.2037G>A p.T679= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs749664188, COSV61171018; called by muse, mutect2, varscan2
- VSIG1 | c.546C>T p.I182= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs777401121, COSV54257360, COSV99480517; called by muse, mutect2, varscan2
- GNAO1 | c.723+7049G>A | Intron (SNP) | VAF 24/92 reads (26%) | catalogued as rs1330301776, COSV52609806; called by muse, mutect2, varscan2
- MACF1 | c.15832-11346T>C | Intron (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57103662; called by muse, mutect2, varscan2
- MIR450A2 | n.10G>T | RNA (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2
